Somatic mutation profile of tumor specimen TCGA-49-4514-01A (aliquot TCGA-49-4514-01A-21D-1855-08) from TCGA case TCGA-49-4514, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 79.1 years (28,908 days).
Specimen TCGA-49-4514-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 18e07a6f-9c1f-474e-92d9-47c426f715b5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-49-4514-11A (Solid Tissue Normal), aliquot TCGA-49-4514-11A-01D-1855-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aa1fcf91-1c88-4aba-9180-18195cbaec6e

The open-access MAF lists 349 somatic variants for this specimen: 252 protein-altering or splice-affecting, 90 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 215, Silent 90, Nonsense Mutation 18, Splice Site 7, Frame Shift Del 7, Intron 3, 3'Flank 2, Frame Shift Ins 2, Splice Region 1, Nonstop Mutation 1, Translation Start Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KEAP1 | c.1408C>A p.R470S | Missense Mutation (SNP) | VAF 11/50 reads (22%) | hotspot (GDC flag); SIFT tolerated (0.1); PolyPhen possibly damaging (0.899); catalogued as COSV50260643, COSV50262012; called by muse, mutect2, varscan2
- RIT1 | c.270G>T p.M90I | Missense Mutation (SNP) | VAF 12/61 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs483352822, CM136419, CM148229, COSV64170809, COSV64170843, COSV64170960; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 25/65 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- XPO6 | c.820A>G p.I274V | Missense Mutation (SNP) | VAF 18/91 reads (20%) | hotspot (GDC flag); SIFT tolerated (0.27); PolyPhen benign (0.306); catalogued as rs1327332306, COSV100484624; called by muse, mutect2, varscan2
- ABCA12 | c.3499G>A p.V1167I (on ENST00000272895 / NM_173076.3; = p.V849I on NM_015657.3) | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.559); catalogued as COSV55962925; called by muse, mutect2, varscan2
- AC098582.1 | c.577G>T p.A193S | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs1408550332, COSV52023212; called by muse, mutect2, varscan2
- ACKR1 | c.757T>C p.W253R | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63674803; called by muse, mutect2, varscan2
- ACOT12 | c.1214G>A p.R405H | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs576654714, COSV56892736; called by muse, mutect2, varscan2
- ADAMTS18 | c.1978A>T p.S660C | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV51423811; called by muse, mutect2, varscan2
- ADH4 | c.128C>A p.A43D | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55502809; called by muse, mutect2, varscan2
- AGL | c.2847G>T p.K949N | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV54051877, COSV54059445; called by muse, mutect2, varscan2
- AHNAK | c.2182G>T p.G728C | Missense Mutation (SNP) | VAF 81/496 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV57232948; called by muse, mutect2, varscan2
- AKAP17A | c.601G>A p.G201S | Missense Mutation (SNP) | VAF 25/188 reads (13%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.923); catalogued as COSV58312368; called by muse, mutect2, varscan2
- ALDH3A2 | c.418A>T p.S140C | Missense Mutation (SNP) | VAF 40/173 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.9); catalogued as COSV51568982; called by muse, mutect2, varscan2
- ALMS1 | c.7175C>T p.P2392L | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1384040049, COSV52523267; called by muse, mutect2, varscan2
- AMER3 | c.1828G>A p.E610K | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as COSV58466836; called by muse, mutect2, varscan2
- ANKRD55 | c.1744C>T p.R582W | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs143274111, COSV61951207; called by muse, varscan2
- APPBP2 | c.299C>G p.S100* | Nonsense Mutation (SNP) | VAF 13/98 reads (13%) | catalogued as COSV50027951, COSV50030141; called by muse, mutect2, varscan2
- ARHGAP19 | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.046); catalogued as COSV100363373; called by muse, mutect2, varscan2
- ARMH4 | c.1054G>T p.G352C | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as COSV99957384, COSV99959127; called by muse, mutect2, varscan2
- ARMH4 | c.1053G>T p.E351D | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV99957386, COSV99959129; called by muse, mutect2, varscan2
- ASPM | c.398A>G p.Q133R | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV54139882; called by muse, mutect2, varscan2
- ATF6B | c.1153-1G>A p.X385_splice | Splice Site (SNP) | VAF 9/83 reads (11%) | catalogued as COSV64352757; called by muse, mutect2, varscan2
- ATOH1 | c.284C>A p.P95H | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV100024596; called by muse, mutect2, varscan2
- ATP10A | c.1453G>A p.G485S | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.041); catalogued as rs759871370, COSV63523776; called by muse, mutect2, varscan2
- ATP4A | c.726C>A p.C242* | Nonsense Mutation (SNP) | VAF 13/119 reads (11%) | catalogued as COSV52872340; called by muse, mutect2, varscan2
- ATXN1 | c.1132G>A p.V378I | Missense Mutation (SNP) | VAF 38/217 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.185); catalogued as COSV55232765; called by muse, mutect2, varscan2
- BEND6 | c.268C>T p.R90* | Nonsense Mutation (SNP) | VAF 36/259 reads (14%) | catalogued as rs928555916, COSV66070555; called by muse, mutect2, varscan2
- BMS1 | c.2465A>T p.K822M | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV65735725; called by muse, mutect2, varscan2
- BPHL | c.282G>T p.W94C | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV66744675; called by muse, mutect2, varscan2
- BRINP1 | c.679C>A p.L227I | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV56314632; called by muse, mutect2
- BRWD3 | c.4465G>T p.A1489S | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.018); catalogued as COSV64754125; called by muse, mutect2, varscan2
- CACHD1 | c.772A>G p.I258V | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV51560666; called by muse, mutect2, varscan2
- CACNG5 | c.629A>T p.Y210F | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.587); catalogued as COSV50060552, COSV99400791; called by muse, mutect2, varscan2
- CALCA | c.373G>T p.D125Y | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.705); catalogued as COSV100524130, COSV100524134; called by muse, mutect2, varscan2
- CALCOCO1 | c.648G>C p.R216S | Missense Mutation (SNP) | VAF 75/518 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.371); catalogued as COSV50426569; called by muse, mutect2, varscan2
- CAPRIN1 | c.791C>T p.S264L | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.036); catalogued as COSV58222515; called by muse, mutect2, varscan2
- CDH10 | c.1793G>T p.C598F | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52600072; called by muse, mutect2, varscan2
- CDH18 | c.1987G>T p.G663C | Missense Mutation (SNP) | VAF 91/327 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56964858; called by muse, mutect2, varscan2
- CDH2 | c.1502C>G p.P501R | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.28); catalogued as COSV52297971; called by muse, mutect2, varscan2
- CDH3 | c.1756G>T p.D586Y | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV50577685; called by muse, mutect2, varscan2
- CDH8 | c.1210G>T p.A404S | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.734); catalogued as COSV54866779, COSV54868931; called by muse, mutect2, varscan2
- CEP192 | c.7580T>G p.I2527S | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV58071245; called by muse, mutect2
- CHEK2 | c.53G>C p.C18S | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.065); catalogued as rs151218932, COSV60427130; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CIP2A | c.2538G>C p.L846F | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV55418040; called by muse, mutect2, varscan2
- CNKSR2 | c.1722G>T p.E574D | Missense Mutation (SNP) | VAF 43/233 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as COSV54267107; called by muse, mutect2, varscan2
- CNOT2 | c.929C>T p.S310L | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV57507485; called by muse, mutect2, varscan2
- CNTNAP2 | c.1422C>G p.I474M | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV62265795; called by muse, mutect2, varscan2
- COBL | c.2357G>T p.S786I | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.029); catalogued as COSV54360155; called by muse, mutect2, varscan2
- COL3A1 | c.1409C>A p.P470H | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV58597545; called by muse, mutect2, varscan2
- CSMD3 | c.6685C>G p.P2229A (on ENST00000297405 / NM_001363185.1; = p.P2125A on NM_052900.3) | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV52176878, COSV52334643; called by muse, mutect2, varscan2
- CSMD3 | c.1988G>T p.S663I (on ENST00000297405 / NM_001363185.1; = p.S559I on NM_052900.3) | Missense Mutation (SNP) | VAF 44/263 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.362); catalogued as COSV52334664; called by muse, mutect2
- CSMD3 | c.1986A>T p.E662D (on ENST00000297405 / NM_001363185.1; = p.E558D on NM_052900.3) | Missense Mutation (SNP) | VAF 40/255 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.41); catalogued as COSV52334684; called by muse, mutect2
- CTCFL | c.1936G>C p.E646Q | Missense Mutation (SNP) | VAF 31/239 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV54770144; called by muse, mutect2, varscan2
- CTCFL | c.1071G>C p.L357F | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV54779408; called by muse, mutect2, varscan2
- CYBB | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV66086486; called by muse, mutect2, varscan2
- DAXX | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs780256009, COSV56473197; called by muse, mutect2, varscan2
- DCLRE1A | c.2257G>A p.E753K | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100800511; called by muse, mutect2, varscan2
- DEFB119 | c.62G>C p.G21A | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.238); catalogued as COSV99489383; called by muse, mutect2, varscan2
- DIDO1 | c.4231G>C p.E1411Q | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV56635059; called by muse, mutect2
- DKK2 | c.356G>T p.S119I | Missense Mutation (SNP) | VAF 31/239 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV53404175; called by muse, mutect2, varscan2
- DLL3 | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.828); catalogued as COSV52696979; called by muse, mutect2, varscan2
- DOCK4 | c.1132G>C p.V378L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV70324578, COSV70324581, COSV70326824; called by muse, mutect2, varscan2
- DROSHA | c.3577G>T p.E1193* | Nonsense Mutation (SNP) | VAF 26/198 reads (13%) | catalogued as COSV60783557; called by muse, mutect2, varscan2
- DZIP1L | c.2140C>T p.Q714* | Nonsense Mutation (SNP) | VAF 39/282 reads (14%) | catalogued as COSV100551386, COSV59523777; called by muse, mutect2, varscan2
- ELP1 | c.1451A>T p.K484M | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV65900185; called by muse, varscan2
- ESRRG | c.934G>C p.G312R | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV63183261; called by muse, mutect2
- F13B | c.1525del p.E509Kfs*2 | Frame Shift Del (DEL) | VAF 12/79 reads (15%) | catalogued as COSV66374825; called by pindel, varscan2
- F13B | c.1498G>T p.E500* | Nonsense Mutation (SNP) | VAF 13/84 reads (15%) | catalogued as CD011868, COSV66375903; called by muse, varscan2
- FAM160B1 | c.1025A>G p.Y342C | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.631); catalogued as COSV65089910; called by muse, mutect2, varscan2
- FAM71B | c.935C>G p.A312G | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV57231192, COSV57231592; called by muse, mutect2, varscan2
- FAM71B | c.206T>A p.M69K | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV57231602; called by muse, mutect2, varscan2
- FAT3 | c.12885C>A p.C4295* | Nonsense Mutation (SNP) | VAF 15/61 reads (25%) | catalogued as COSV53078374, COSV53180627; called by muse, mutect2, varscan2
- FBXO43 | c.298G>C p.G100R | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.448); catalogued as COSV101413937; called by muse, mutect2, varscan2
- FCRL2 | c.1489-1G>T p.X497_splice | Splice Site (SNP) | VAF 16/80 reads (20%) | catalogued as COSV100830024; called by muse, mutect2, varscan2
- FER1L6 | c.4601C>A p.S1534Y | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.949); catalogued as COSV67550691, COSV67553066; called by muse, mutect2, varscan2
- FLG | c.10406C>A p.S3469Y | Missense Mutation (SNP) | VAF 117/669 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64250901, COSV99056750; called by muse, mutect2, varscan2
- FREM2 | c.1258G>C p.A420P | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV54854364; called by muse, mutect2, varscan2
- FTHL17 | c.240C>G p.H80Q | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.09); catalogued as COSV63268007; called by muse, mutect2, varscan2
- GALNT17 | c.689G>T p.R230L | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61176649, COSV61194625; called by muse, mutect2, varscan2
- GAS6 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781147555, COSV59849567; called by muse, mutect2, varscan2
- GBA3 | c.341C>A p.P114H | Missense Mutation (SNP) | VAF 30/251 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV72438366; called by muse, mutect2, varscan2
- GCN1 | c.4408G>A p.D1470N | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56115531; called by muse, mutect2, varscan2
- GNG2 | c.195G>T p.K65N | Missense Mutation (SNP) | VAF 38/172 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.447); catalogued as COSV58920430; called by muse, mutect2, varscan2
- GPD1 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56549252; called by muse, mutect2, varscan2
- GRIFIN | c.76G>C p.D26H | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV101321772, COSV101321776; called by muse, mutect2, varscan2
- GRIN2A | c.3011C>A p.S1004Y | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.601); catalogued as COSV58040521, COSV58053029, COSV58058373; called by muse, mutect2, varscan2
- GTF2IRD1 | c.929C>G p.T310S | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as COSV56092384; called by muse, varscan2
- HAPLN4 | c.970G>T p.A324S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.657); catalogued as COSV52271614; called by muse, mutect2
- HCLS1 | c.1156A>T p.R386W | Missense Mutation (SNP) | VAF 50/332 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.43); catalogued as COSV57528230; called by muse, mutect2, varscan2
- HEG1 | c.2890A>T p.K964* | Nonsense Mutation (SNP) | VAF 11/48 reads (23%) | catalogued as COSV60766064; called by muse, mutect2, varscan2
- HMCN1 | c.6806G>T p.C2269F | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV54945712; called by muse, mutect2, varscan2
- HTR1A | c.996G>C p.K332N | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV60503217; called by muse, mutect2, varscan2
- IFNA21 | c.137G>T p.R46I | Missense Mutation (SNP) | VAF 45/255 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV66518988; called by muse, mutect2, varscan2
- IGHG3 | c.826C>A p.P276T | Missense Mutation (SNP) | VAF 41/211 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs745859846; called by muse, mutect2, varscan2
- IGSF21 | c.583C>A p.L195I | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as COSV52127025, COSV52145721; called by muse, mutect2, varscan2
- INS-IGF2 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.52); catalogued as COSV51748579; called by muse, mutect2, varscan2
- INSRR | c.2306G>T p.R769L | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs1461335599, COSV63877744; called by muse, mutect2
- IRS1 | c.2015C>G p.S672C | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59340743; called by muse, mutect2, varscan2
- ITFG2 | c.406+1G>A p.X136_splice | Splice Site (SNP) | VAF 3/38 reads (8%) | catalogued as COSV57391303; called by muse, mutect2
- JAK2 | c.3334C>T p.Q1112* | Nonsense Mutation (SNP) | VAF 11/64 reads (17%) | catalogued as COSV67682662; called by muse, mutect2, varscan2
- KAT6B | c.4534G>T p.A1512S | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.055); catalogued as COSV54755656; called by muse, mutect2, varscan2
- KBTBD6 | c.1759G>A p.E587K | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as COSV65272076; called by muse, mutect2, varscan2
- KCNT2 | c.218G>T p.S73I | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as COSV54111937; called by muse, mutect2, varscan2
- KIAA1109 | c.2336C>G p.S779C | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.628); catalogued as COSV52695346, COSV99156803; called by muse, mutect2, varscan2
- KIAA1755 | c.199T>A p.C67S | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54081316; called by muse, mutect2
- KIF21A | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV100735724; called by muse, mutect2, varscan2
- KRT26 | c.653T>C p.L218S | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV59416021; called by muse, mutect2, varscan2
- KRT78 | c.284C>A p.P95Q | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100467037; called by muse, mutect2, varscan2
- KRT78 | c.283C>A p.P95T | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100467704; called by muse, mutect2, varscan2
- KRTAP10-9 | c.728G>T p.C243F | Missense Mutation (SNP) | VAF 47/215 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as COSV59981982; called by muse, mutect2, varscan2
- KRTAP27-1 | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.031); catalogued as COSV67001716; called by muse, mutect2, varscan2
- LRBA | c.5162C>A p.S1721Y | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100842141; called by muse, mutect2, varscan2
- LRIT3 | c.1066G>C p.D356H | Missense Mutation (SNP) | VAF 39/271 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.473); catalogued as COSV59987921; called by muse, mutect2, varscan2
- LRRTM1 | c.949G>T p.D317Y | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.744); catalogued as COSV54447283; called by muse, mutect2
- LYST | c.2048C>G p.S683C | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV67714946; called by muse, mutect2, varscan2
- MAP1B | c.4778C>T p.S1593F | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as COSV57107286; called by muse, mutect2, varscan2
- MAP1LC3C | c.385G>T p.E129* | Nonsense Mutation (SNP) | VAF 6/84 reads (7%) | catalogued as COSV61804153; called by muse, mutect2
- MAST1 | c.1600C>G p.H534D | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52256085; called by muse, mutect2, varscan2
- MEPCE | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 29/159 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV52770118; called by muse, mutect2, varscan2
- MGAT5 | c.1249C>A p.H417N | Missense Mutation (SNP) | VAF 58/368 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56101642, COSV99924463; called by muse, mutect2, varscan2
- MMRN1 | c.3037G>T p.A1013S | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs372333120, COSV53334711; called by muse, mutect2, varscan2
- MPP1 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV65728954; called by muse, mutect2, varscan2
- MRGPRX3 | c.738G>A p.W246* | Nonsense Mutation (SNP) | VAF 13/104 reads (13%) | catalogued as rs902150270, COSV66934833, COSV66934931; called by muse, mutect2, varscan2
- MS4A5 | c.602G>T p.*201Lext*4 | Nonstop Mutation (SNP) | VAF 20/129 reads (16%) | catalogued as COSV55742834; called by muse, mutect2, varscan2
- MS4A8 | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.265); catalogued as rs1343383898, COSV55756152; called by muse, mutect2, varscan2
- MTO1 | c.248G>T p.G83V | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1420716921, COSV64775128; called by muse, mutect2, varscan2
- MUC16 | c.21911C>A p.S7304Y | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.26); catalogued as COSV67481941, COSV67497680; called by muse, mutect2, varscan2
- MUC5B | c.14819C>G p.S4940C | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV71595958; called by muse, mutect2, varscan2
- MYBL2 | c.1536G>T p.M512I | Missense Mutation (SNP) | VAF 32/270 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV53834137; called by muse, mutect2, varscan2
- MYH4 | c.4822G>A p.E1608K | Missense Mutation (SNP) | VAF 15/288 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as COSV55127345; called by muse, mutect2
- MYH6 | c.5483T>A p.L1828Q | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV59307945; called by muse, mutect2, varscan2
- MYH8 | c.4643A>T p.E1548V | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV67961292, COSV67973498; called by muse, mutect2, varscan2
- NAV3 | c.3554G>C p.G1185A | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.996); catalogued as COSV57077752, COSV57115100; called by muse, mutect2, varscan2
- NCF1 | c.233C>A p.P78H | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.715); catalogued as COSV56877505; called by muse, mutect2, varscan2
- NCF4 | c.815A>T p.E272V | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.031); catalogued as COSV99957564; called by muse, mutect2, varscan2
- NEK11 | c.946C>T p.H316Y | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63580693; called by muse, mutect2, varscan2
- NFATC2 | c.2423C>T p.S808L | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as rs779382116, COSV65352933; called by muse, mutect2, varscan2
- NLRP4 | c.1805T>A p.L602H | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56707318; called by muse, mutect2, varscan2
- NOCT | c.982G>C p.E328Q | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); catalogued as COSV99763979; called by muse, mutect2, varscan2
- NR2F2 | c.673G>T p.E225* | Nonsense Mutation (SNP) | VAF 72/178 reads (40%) | catalogued as COSV67684220; called by muse, mutect2, varscan2
- NRK | c.1319A>C p.Q440P | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV54608054; called by muse, mutect2, varscan2
- NRXN1 | c.883G>T p.D295Y | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58492305, COSV58497652; called by muse, mutect2, varscan2
- NTRK3 | c.1604G>T p.R535M | Missense Mutation (SNP) | VAF 40/215 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV62313946; called by muse, mutect2, varscan2
- OBSCN | c.3365T>C p.M1122T | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as COSV52836011; called by muse, mutect2, varscan2
- OR13G1 | c.324G>C p.E108D | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100687123, COSV100687619; called by muse, mutect2, varscan2
- OR2B6 | c.423C>A p.C141* | Nonsense Mutation (SNP) | VAF 31/216 reads (14%) | catalogued as COSV55129883, COSV99773860; called by muse, mutect2, varscan2
- OR4C6 | c.574A>G p.I192V | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.005); catalogued as COSV58606579; called by muse, mutect2, varscan2
- OR4S2 | c.237G>C p.M79I | Missense Mutation (SNP) | VAF 53/296 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV100412864, COSV56748527; called by muse, mutect2, varscan2
- OR51L1 | c.743G>C p.C248S | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV58625959; called by muse, mutect2, varscan2
- OR52B4 | c.829C>G p.P277A | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV68768566, COSV68769571; called by muse, mutect2
- OR5K3 | c.710C>A p.S237Y | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs749485140, COSV67350242; called by muse, mutect2, varscan2
- OR5L2 | c.730C>A p.H244N | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1201959601, COSV65725305; called by muse, mutect2
- OR8J1 | c.38T>C p.I13T | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.283); catalogued as COSV57320305; called by muse, mutect2, varscan2
- OTUD7A | c.667C>G p.H223D | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61038690, COSV61044032; called by muse, mutect2, varscan2
- OTUD7A | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61038370, COSV61044043; called by muse, mutect2, varscan2
- PAM | c.1517G>C p.G506A | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.726); catalogued as COSV99173904; called by muse, mutect2, varscan2
- PASD1 | c.207+1G>T p.X69_splice | Splice Site (SNP) | VAF 17/104 reads (16%) | catalogued as COSV64858059; called by muse, mutect2, varscan2
- PCDHB7 | c.302C>A p.P101H | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV50768493; called by muse, mutect2, varscan2
- PCDHB7 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50823311; called by muse, mutect2, varscan2
- PDE10A | c.1136G>C p.C379S | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63050506; called by muse, mutect2, varscan2
- PDIA4 | c.1420G>T p.D474Y (on ENST00000286091 / NM_001371244.1; = p.D473Y on NM_004911.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as COSV53727158; called by muse, mutect2, varscan2
- PDS5B | c.1522G>A p.D508N | Missense Mutation (SNP) | VAF 35/199 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.818); catalogued as COSV59735335; called by muse, mutect2, varscan2
- PJA1 | c.1015C>T p.P339S (on ENST00000361478 / NM_145119.4; = p.P151S on NM_022368.5) | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV64053846; called by mutect2, varscan2
- PML | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs146344435; called by mutect2, varscan2
- PNPT1 | c.1558G>T p.E520* | Nonsense Mutation (SNP) | VAF 21/108 reads (19%) | catalogued as COSV53175998, COSV53180427; called by muse, mutect2, varscan2
- PORCN | c.748T>A p.S250T (on ENST00000326194 / NM_203475.3; = p.S239T on NM_022825.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV100400583; called by muse, mutect2, varscan2
- PPRC1 | c.343-1G>C p.X115_splice | Splice Site (SNP) | VAF 10/100 reads (10%) | catalogued as COSV53388998; called by muse, mutect2
- PSG6 | c.25T>C p.C9R | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.011); catalogued as COSV51838709; called by muse, mutect2, varscan2
- PSG8 | c.638G>C p.G213A | Missense Mutation (SNP) | VAF 72/502 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV60616365; called by muse, mutect2, varscan2
- PTPN3 | c.1652C>G p.P551R | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52711624; called by muse, mutect2, varscan2
- PTPRH | c.1165G>T p.V389L | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as COSV54750728; called by muse, mutect2, varscan2
- PTPRR | c.352G>A p.V118M | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.391); catalogued as COSV51749420; called by muse, mutect2, varscan2
- RALGAPA1 | c.3200G>C p.R1067T | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51898631; called by muse, mutect2, varscan2
- RAPGEF6 | c.1957G>C p.E653Q | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.84); catalogued as COSV99728286; called by muse, mutect2, varscan2
- RBFOX1 | c.412G>T p.G138C | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV60985956; called by muse, mutect2, varscan2
- RELN | c.5476G>T p.G1826W | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59036557; called by muse, mutect2, varscan2
- RFC1 | c.3357G>C p.M1119I (on ENST00000381897 / NM_001363496.2; = p.M1118I on NM_002913.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV56470651; called by muse, mutect2, varscan2
- RGS7 | c.256G>T p.A86S | Missense Mutation (SNP) | VAF 32/177 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.895); catalogued as COSV58562687; called by muse, mutect2, varscan2
- ROBO4 | c.1880G>A p.R627H | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs774678606, COSV100127234, COSV60623778; called by muse, mutect2, varscan2
- RP1L1 | c.3391G>A p.D1131N | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as COSV66760941; called by muse, mutect2, varscan2
- RPA4 | c.187G>A p.V63M | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as COSV100235678; called by muse, mutect2, varscan2
- RTN1 | c.1585G>A p.E529K | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV50752846; called by muse, mutect2, varscan2
- RYR2 | c.11158G>A p.E3720K | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV63699076, COSV63718023; called by muse, mutect2, varscan2
- SCAP | c.1109C>G p.S370* | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | catalogued as COSV55566475; called by muse, mutect2, varscan2
- SCP2 | c.840G>A p.M280I | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV65262720; called by muse, mutect2, varscan2
- SEMA5B | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV52109338; called by muse, mutect2
- SETBP1 | c.1319G>T p.G440V | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV56338421; called by muse, mutect2, varscan2
- SFSWAP | c.2159C>T p.P720L | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as rs767758310, COSV55526370; called by muse, mutect2, varscan2
- SH3GL3 | c.713G>A p.S238N | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV61062185; called by muse, mutect2, varscan2
- SHROOM2 | c.809C>A p.P270H | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV66611077; called by muse, mutect2, varscan2
- SI | c.1006C>T p.Q336* | Nonsense Mutation (SNP) | VAF 11/75 reads (15%) | catalogued as COSV52290758; called by muse, mutect2, varscan2
- SLC17A6 | c.1517C>A p.A506E | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs764346080, COSV54142368; called by muse, mutect2, varscan2
- SLC46A1 | c.670C>G p.L224V | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as COSV100398159; called by muse, mutect2, varscan2
- SLC6A18 | c.46G>T p.D16Y | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV57254799; called by muse, mutect2
- SLC7A1 | c.511A>G p.I171V | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.491); catalogued as rs1043404736, COSV66332016; called by muse, mutect2, varscan2
- SLCO2B1 | c.347G>T p.R116L | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56934315, COSV56940034; called by muse, mutect2, varscan2
- SLCO6A1 | c.16G>T p.A6S | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.01); catalogued as COSV65806754, COSV65815279; called by muse, mutect2, varscan2
- SMARCC2 | c.1513G>A p.E505K | Missense Mutation (SNP) | VAF 40/230 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57225615; called by muse, varscan2
- SMC1B | c.2747A>T p.Q916L | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV62533780; called by muse, mutect2, varscan2
- SNX25 | c.763G>C p.E255Q | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV53019150, COSV99253669; called by muse, mutect2, varscan2
- SPATA32 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 56/250 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.056); catalogued as rs765864683, COSV59303287; called by muse, mutect2, varscan2
- SPEF2 | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 26/254 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56799005; called by muse, mutect2
- SPTA1 | c.5740G>T p.A1914S | Missense Mutation (SNP) | VAF 35/237 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.023); catalogued as rs1374615624, COSV63760521; called by muse, mutect2, varscan2
- SRPX | c.1046C>T p.T349I | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.543); catalogued as COSV100656290; called by muse, mutect2, varscan2
- SRPX2 | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs778904903, COSV65934750; called by muse, mutect2, varscan2
- SRRM2 | c.4888C>T p.R1630W | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs751165203, COSV57071442; called by muse, mutect2, varscan2
- STAM | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as COSV66352290; called by muse, mutect2
- STK4 | c.1383G>C p.E461D | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.168); catalogued as rs771492682, COSV65672245; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SULT6B1 | c.432T>A p.D144E (on ENST00000535679 / NM_001367551.1; = p.D106E on NM_001032377.2) | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53193879; called by muse, mutect2
- SUV39H1 | c.649C>A p.L217M | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.045); catalogued as COSV61921450; called by muse, mutect2, varscan2
- SYAP1 | c.982G>T p.E328* | Nonsense Mutation (SNP) | VAF 31/235 reads (13%) | catalogued as COSV66469044; called by muse, mutect2, varscan2
- SYCP3 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV57150283; called by muse, mutect2, varscan2
- SYK | c.890C>G p.S297C | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.299); catalogued as COSV65325329, COSV65330744; called by muse, mutect2, varscan2
- SYTL5 | c.2160G>T p.M720I | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as COSV52906180; called by muse, mutect2, varscan2
- TBCD | c.1312G>T p.V438L | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as rs770119863, COSV62808695; called by muse, mutect2, varscan2
- TBX20 | c.40C>T p.R14W | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV101282434; called by muse, mutect2, varscan2
- TBX22 | c.1462G>T p.G488C | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as COSV64788110; called by muse, mutect2, varscan2
- TCF20 | c.3475G>A p.E1159K | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.081); catalogued as COSV59496502; called by muse, mutect2, varscan2
- TCOF1 | c.2463G>C p.Q821H (on ENST00000377797 / NM_001135243.1; = p.Q744H on NM_000356.4) | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.916); catalogued as COSV60355141; called by muse, mutect2, varscan2
- TENM2 | c.8158G>C p.E2720Q (on ENST00000518659 / NM_001122679.2; = p.E2481Q on NM_001080428.3) | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.754); catalogued as rs751228959, COSV69143314; called by muse, mutect2, varscan2
- TENT4A | c.1227G>A p.M409I | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV50102864; called by muse, mutect2, varscan2
- TEX10 | c.475G>T p.D159Y | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100887762, COSV66518952; called by muse, mutect2, varscan2
- TFE3 | c.449C>T p.P150L | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.376); catalogued as COSV59949470; called by muse, mutect2, varscan2
- THBS2 | c.251T>G p.F84C | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64682497; called by muse, mutect2, varscan2
- TMEM132D | c.3157G>A p.V1053I | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750913130, COSV67160883; called by muse, mutect2, varscan2
- TMEM209 | c.777G>C p.G259= | Splice Region (SNP) | VAF 33/159 reads (21%) | catalogued as COSV61023803; called by muse, mutect2, varscan2
- TOP2B | c.1341G>T p.K447N (on ENST00000264331 / NM_001330700.2; = p.K442N on NM_001068.3) | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV51977823; called by muse, mutect2, varscan2
- TRIM49 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769538739, COSV61670522; called by muse, mutect2, varscan2
- TSC22D1 | c.321G>C p.K107N | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV71776474; called by muse, mutect2, varscan2
- TTN | c.23093C>T p.S7698L (on ENST00000591111; = p.S6771L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/164 reads (17%) | PolyPhen benign (0.011); catalogued as COSV59862653; called by muse, mutect2, varscan2
- TUSC3 | c.85C>T p.L29F | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.86); catalogued as rs545107135, COSV65887404; called by muse, mutect2, varscan2
- TYR | c.1360G>A p.D454N | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV54483770, COSV54487043; called by muse, mutect2, varscan2
- ULK4 | c.617del p.G206Afs*22 | Frame Shift Del (DEL) | VAF 32/178 reads (18%) | catalogued as COSV57218369; called by mutect2, pindel, varscan2
- USH2A | c.9809G>A p.R3270K | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.75); PolyPhen benign (0.005); catalogued as COSV56337746; called by muse, mutect2, varscan2
- VPS4B | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV53071029; called by muse, mutect2, varscan2
- WDFY3 | c.1887+1G>T p.X629_splice | Splice Site (SNP) | VAF 27/224 reads (12%) | catalogued as COSV55715145; called by muse, mutect2, varscan2
- XRN2 | c.898G>C p.E300Q | Missense Mutation (SNP) | VAF 23/187 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.057); catalogued as COSV65871848; called by muse, mutect2, varscan2
- ZFHX4 | c.7955G>A p.W2652* | Nonsense Mutation (SNP) | VAF 24/134 reads (18%) | catalogued as COSV50747687, COSV51496723; called by muse, mutect2, varscan2
- ZIM3 | c.1001C>A p.P334H | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as COSV54147147; called by muse, mutect2, varscan2
- ZKSCAN2 | c.1842G>T p.Q614H | Missense Mutation (SNP) | VAF 37/220 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.451); catalogued as COSV60159053; called by muse, mutect2
- ZNF217 | c.728C>A p.A243D | Missense Mutation (SNP) | VAF 32/245 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV56594990, COSV56603109; called by muse, mutect2, varscan2
- ZNF79 | c.1063C>T p.H355Y | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61072020; called by muse, mutect2, varscan2
- ZSWIM2 | c.971G>T p.R324I | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as rs996906965, COSV54580207; called by muse, mutect2, varscan2
- GFRAL | c.122del p.A41Vfs*4 | Frame Shift Del (DEL) | VAF 6/39 reads (15%) | called by mutect2, pindel*, varscan2
- GNAI1 | c.884_885del p.T295Ifs*2 | Frame Shift Del (DEL) | VAF 11/71 reads (15%) | called by pindel, varscan2
- MRPS15 | c.637-2A>T p.X213_splice | Splice Site (SNP) | VAF 21/106 reads (20%) | called by muse, mutect2
- OR5F1 | c.926_927insT p.R309Sfs*? | Frame Shift Ins (INS) | VAF 7/48 reads (15%) | called by mutect2, pindel*
- RANBP3L | c.799del p.L267* | Frame Shift Del (DEL) | VAF 33/100 reads (33%) | called by mutect2, pindel, varscan2
- RELN | c.4717dup p.T1573Nfs*21 | Frame Shift Ins (INS) | VAF 24/141 reads (17%) | called by mutect2, pindel, varscan2
- SRRM2 | c.5016del p.R1673Gfs*25 | Frame Shift Del (DEL) | VAF 13/61 reads (21%) | called by mutect2, pindel, varscan2
- ZFHX4 | c.8456del p.G2819Efs*15 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | called by mutect2, pindel, varscan2
- ABCC11 | c.609G>A p.V203= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV62322867, COSV62326182; called by muse, mutect2
- AC006059.2 | c.1230C>T p.L410= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as rs1559649017, COSV59609826; called by muse, mutect2
- ADAM29 | c.1410T>A p.G470= | Silent (SNP) | VAF 24/149 reads (16%) | catalogued as rs758993829, COSV100822284; called by muse, mutect2, varscan2
- ADAM32 | c.1122G>T p.V374= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV65954044; called by mutect2, varscan2
- ADGRF4 | c.828C>A p.P276= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as rs765685456, COSV51951050; called by muse, mutect2, varscan2
- ANKRD13C | c.156G>A p.K52= | Silent (SNP) | VAF 30/217 reads (14%) | catalogued as COSV52035729; called by muse, mutect2, varscan2
- ANKRD23 | c.12C>T p.I4= | Silent (SNP) | VAF 71/393 reads (18%) | catalogued as COSV58413522; called by muse, mutect2, varscan2
- ARL5A | c.408A>G p.A136= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV99706831; called by muse, mutect2, varscan2
- ASL | c.660C>G p.L220= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as COSV59189603; called by muse, mutect2
- AURKAIP1 | c.489A>G p.R163= | Silent (SNP) | VAF 27/112 reads (24%) | catalogued as COSV100408770; called by muse, mutect2, varscan2
- BAIAP2 | c.234G>A p.Q78= | Silent (SNP) | VAF 39/260 reads (15%) | catalogued as COSV100348968; called by muse, mutect2, varscan2
- CADM3 | c.963G>T p.P321= (on ENST00000368125 / NM_001127173.3; = p.P355= on NM_021189.5) | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as rs753580284, COSV63676528, COSV63677532; called by mutect2, varscan2
- CELF2 | c.1089G>C p.L363= (on ENST00000416382 / NM_001025077.3; = p.L376= on NM_006561.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 28/155 reads (18%) | catalogued as COSV100258579; called by muse, mutect2, varscan2
- CNST | c.2067C>T p.F689= | Silent (SNP) | VAF 17/122 reads (14%) | catalogued as rs755884853, COSV63622950; called by muse, mutect2, varscan2
- COL2A1 | c.3480T>A p.S1160= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as COSV61534943; called by muse, mutect2, varscan2
- CTNND2 | c.2155C>T p.L719= | Silent (SNP) | VAF 25/123 reads (20%) | catalogued as COSV58931984; called by muse, mutect2, varscan2
- EFCAB6 | c.1401G>C p.L467= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as rs768446176, COSV53073774; called by muse, mutect2, varscan2
- EIF3B | c.1563G>A p.K521= | Silent (SNP) | VAF 16/140 reads (11%) | catalogued as rs753688567, COSV62805254, COSV62805739; called by muse, mutect2, varscan2
- ERLEC1 | c.1407C>A p.I469= | Silent (SNP) | VAF 24/158 reads (15%) | catalogued as COSV51753835; called by muse, mutect2, varscan2
- ERMP1 | c.1647G>A p.S549= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as rs775253188, COSV53039770; called by mutect2, varscan2
- FAM114A1 | c.1677G>A p.L559= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as rs774296251, COSV62675230; called by muse, mutect2, varscan2
- FAM9A | c.480A>G p.Q160= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV66813800; called by muse, mutect2
- FAT3 | c.12690C>A p.V4230= | Silent (SNP) | VAF 31/191 reads (16%) | catalogued as rs1423425083, COSV53180602, COSV99967440; called by muse, mutect2, varscan2
- FZD8 | c.1398G>A p.P466= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV101020230; called by muse, mutect2
- GALNT9 | c.1200C>A p.A400= (on ENST00000328957 / NM_001122636.2; = p.A34= on NM_021808.3) | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV61103985; called by muse, mutect2, varscan2
- GALNTL6 | c.768C>A p.I256= | Silent (SNP) | VAF 11/87 reads (13%) | catalogued as COSV72494370; called by muse, mutect2, varscan2
- GBA3 | c.342C>T p.P114= | Silent (SNP) | VAF 30/253 reads (12%) | catalogued as rs756832208, COSV101545581; called by muse, mutect2, varscan2
- GMPR2 | c.1008C>T p.V336= (on ENST00000355299 / NM_001351022.2; = p.V354= on NM_016576.5) | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV57470848; called by muse, mutect2, varscan2
- GNAZ | c.603C>T p.D201= | Silent (SNP) | VAF 21/179 reads (12%) | catalogued as rs375941406; called by muse, mutect2, varscan2
- GPC4 | c.1434A>T p.A478= | Silent (SNP) | VAF 28/143 reads (20%) | catalogued as rs749640444, COSV63700074; called by muse, mutect2, varscan2
- GPSM1 | c.126C>T p.G42= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs138071426; called by muse, mutect2
- GRIN2B | c.609C>T p.L203= | Silent (SNP) | VAF 19/149 reads (13%) | catalogued as rs746896701, COSV74208235; called by muse, mutect2, varscan2
- GRM1 | c.783C>A p.I261= | Silent (SNP) | VAF 20/93 reads (22%) | catalogued as COSV51367711; called by muse, mutect2, varscan2
- H2AC13 | c.237C>A p.I79= | Silent (SNP) | VAF 13/112 reads (12%) | catalogued as COSV100704451, COSV62440441; called by muse, varscan2
- H2BC3 | c.222C>T p.I74= | Silent (SNP) | VAF 17/210 reads (8%) | catalogued as COSV63551610; called by muse, mutect2
- HAPLN4 | c.501C>T p.Y167= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV52271623; called by muse, mutect2, varscan2
- JAM2 | c.315G>A p.G105= | Silent (SNP) | VAF 22/136 reads (16%) | catalogued as rs753030534, COSV57256336; called by muse, mutect2, varscan2
- KDM8 | c.291C>T p.I97= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs199859180, COSV99620106; called by mutect2, varscan2
- KHSRP | c.282G>A p.T94= | Silent (SNP) | VAF 25/124 reads (20%) | catalogued as rs539731278, COSV58599520; called by muse, mutect2, varscan2
- KIAA0100 | c.2544G>A p.L848= | Silent (SNP) | VAF 40/291 reads (14%) | catalogued as rs1333430516, COSV66496806; called by muse, mutect2, varscan2
- KIF14 | c.1737C>A p.T579= | Silent (SNP) | VAF 15/91 reads (16%) | catalogued as COSV66264369; called by muse, mutect2, varscan2
- KIF4A | c.258C>A p.A86= | Silent (SNP) | VAF 21/142 reads (15%) | catalogued as COSV65546177; called by muse, mutect2, varscan2
- L3MBTL3 | c.744G>A p.A248= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs368885807; called by muse, mutect2, varscan2
- LIMCH1 | c.2859A>T p.S953= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV58298472; called by muse, mutect2, varscan2
- LRP4 | c.1014T>A p.G338= | Silent (SNP) | VAF 15/93 reads (16%) | catalogued as COSV66139007; called by muse, mutect2, varscan2
- MAGEA6 | c.879C>T p.I293= | Silent (SNP) | VAF 61/277 reads (22%) | catalogued as rs61751891, COSV100263026; called by muse, mutect2, varscan2
- MAP3K21 | c.2754C>T p.C918= | Silent (SNP) | VAF 18/107 reads (17%) | catalogued as COSV64042817; called by muse, mutect2, varscan2
- MRTFB | c.1257G>T p.V419= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV57962267; called by muse, mutect2, varscan2
- MUC4 | c.15987T>C p.C5329= (on ENST00000463781 / NM_018406.7; = p.C1093= on NM_004532.6) | Silent (SNP) | VAF 8/108 reads (7%) | catalogued as COSV57805472; called by muse, mutect2
- NAT10 | c.2982G>A p.R994= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV54396651; called by muse, mutect2, varscan2
- NOMO1 | c.1152C>G p.L384= | Silent (SNP) | VAF 23/182 reads (13%) | catalogued as COSV55061719; called by muse, mutect2, varscan2
- NUDT21 | c.60C>T p.F20= | Silent (SNP) | VAF 19/158 reads (12%) | catalogued as rs1470938759, COSV55859440; called by muse, mutect2, varscan2
- NXPH3 | c.213G>T p.P71= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV100165600, COSV60871966; called by muse, mutect2, varscan2
- OLFM4 | c.1515C>A p.V505= | Silent (SNP) | VAF 12/91 reads (13%) | catalogued as COSV54580810; called by muse, mutect2, varscan2
- OR2A14 | c.456C>T p.F152= | Silent (SNP) | VAF 44/394 reads (11%) | catalogued as COSV68718394; called by muse, mutect2
- OTOP3 | c.1233C>T p.I411= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as rs758729624, COSV60915264; called by muse, mutect2, varscan2
- PCDH11X | c.561C>T p.L187= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as rs1382233087, COSV100014575, COSV53509124; called by muse, mutect2, varscan2
- PCDHGB3 | c.1023T>C p.N341= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as COSV54043927; called by muse, mutect2, varscan2
- PDE2A | c.2580C>A p.I860= | Silent (SNP) | VAF 29/159 reads (18%) | catalogued as COSV57814598; called by muse, mutect2, varscan2
- PLCL2 | c.2907G>T p.G969= (on ENST00000615277 / NM_001144382.2; = p.G843= on NM_015184.5) | Silent (SNP) | VAF 44/190 reads (23%) | catalogued as rs758286579, COSV67625828; called by muse, mutect2, varscan2
- PORCN | c.747C>A p.V249= (on ENST00000326194 / NM_203475.3; = p.V238= on NM_022825.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/141 reads (14%) | catalogued as COSV100400580; called by muse, mutect2, varscan2
- PROP1 | c.594G>A p.L198= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV100383796; called by muse, mutect2
- PSG2 | c.789G>T p.A263= | Silent (SNP) | VAF 52/348 reads (15%) | catalogued as COSV61544869, COSV61545864; called by muse, varscan2
- PTCHD3 | c.141C>A p.P47= | Silent (SNP) | VAF 20/164 reads (12%) | catalogued as COSV71257305; called by muse, mutect2, varscan2
- RIT1 | c.123C>T p.F41= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV64168115; called by muse, mutect2, varscan2
- RNF115 | c.267C>G p.P89= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as COSV65166110; called by muse, mutect2, varscan2
- RRBP1 | c.3252G>A p.E1084= (on ENST00000377813 / NM_001365613.2; = p.E651= on NM_004587.3) | Silent (SNP) | VAF 6/63 reads (10%) | catalogued as COSV55709429; called by muse, mutect2
- SACS | c.13293G>A p.R4431= | Silent (SNP) | VAF 20/155 reads (13%) | catalogued as rs369776806; called by muse, mutect2, varscan2
- SAMD7 | c.786C>A p.P262= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as COSV59421877; called by muse, mutect2, varscan2
- SLCO2B1 | c.672C>T p.P224= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV56940043, COSV99214625; called by muse, mutect2, varscan2
- SLIT2 | c.3684C>T p.A1228= | Silent (SNP) | VAF 24/158 reads (15%) | catalogued as COSV56570500; called by muse, mutect2, varscan2
- SND1 | c.2490G>T p.V830= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as COSV61250119; called by muse, mutect2, varscan2
- SPAG16 | c.1803C>A p.G601= | Silent (SNP) | VAF 31/156 reads (20%) | catalogued as COSV56979852; called by muse, mutect2, varscan2
- SPATS1 | c.624A>G p.P208= | Silent (SNP) | VAF 22/105 reads (21%) | catalogued as COSV55825225; called by muse, varscan2
- SPNS1 | c.1536G>T p.V512= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as COSV57956974; called by muse, mutect2, varscan2
- SULT1A1 | c.60C>T p.L20= | Silent (SNP) | VAF 10/150 reads (7%) | catalogued as rs767496487, COSV59090877; called by muse, mutect2
- SYT10 | c.9C>T p.F3= | Silent (SNP) | VAF 22/209 reads (11%) | catalogued as rs779410991, COSV57346054; called by muse, mutect2, varscan2
- TFAP2C | c.876G>A p.G292= | Silent (SNP) | VAF 27/88 reads (31%) | catalogued as rs1258253286, COSV52373467; called by muse, mutect2, varscan2
- TGM4 | c.1500C>A p.A500= | Silent (SNP) | VAF 25/118 reads (21%) | catalogued as COSV56096930; called by muse, mutect2, varscan2
- THSD7A | c.1371G>T p.G457= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV70269100, COSV70273759; called by muse, mutect2, varscan2
- TIPARP | c.639C>T p.D213= | Silent (SNP) | VAF 23/89 reads (26%) | catalogued as COSV99904042; called by muse, mutect2, varscan2
- TTN | c.67638C>G p.L22546= (on ENST00000591111; = p.L15122= on NM_003319.4) | Silent (SNP) | VAF 69/463 reads (15%) | catalogued as COSV59932003, COSV60382492; called by muse, mutect2, varscan2
- TTN | c.56178G>T p.R18726= (on ENST00000591111; = p.R11302= on NM_003319.4) | Silent (SNP) | VAF 38/209 reads (18%) | catalogued as COSV60382534; called by muse, mutect2, varscan2
- TUBGCP5 | c.2403C>A p.L801= | Silent (SNP) | VAF 8/58 reads (14%) | called by muse, mutect2, varscan2
- UHRF1BP1L | c.1917A>T p.T639= | Silent (SNP) | VAF 11/83 reads (13%) | catalogued as COSV54443221; called by muse, mutect2, varscan2
- VANGL2 | c.156C>A p.P52= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as COSV63605568; called by muse, mutect2, varscan2
- WHRN | c.636G>A p.K212= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV54335339, COSV99470655; called by muse, mutect2, varscan2
- WNK1 | c.5682G>A p.V1894= (on ENST00000315939 / NM_018979.4; = p.V1646= on NM_014823.3) | Silent (SNP) | VAF 38/98 reads (39%) | catalogued as rs1368141521, COSV60046669; called by muse, mutect2, varscan2
- XPO7 | c.609G>A p.K203= | Silent (SNP) | VAF 49/314 reads (16%) | catalogued as COSV53021042; called by muse, mutect2, varscan2
- ZNF503 | c.1545C>T p.I515= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as rs1475564270, COSV100998047; called by muse, mutect2, varscan2
- CCHCR1 | c.-51-403G>A | Intron (SNP) | VAF 31/112 reads (28%) | catalogued as COSV100883855; called by muse, mutect2, varscan2
- CLDN2 | c.-1C>T | 5'UTR (SNP) | VAF 6/50 reads (12%) | catalogued as COSV100390186; called by muse, varscan2
- MCF2 | chrX:139646823 C>A | 5'Flank (SNP) | VAF 5/26 reads (19%) | catalogued as COSV58496094; called by muse, mutect2
- PARP10 | chr8:143975364 C>A | 3'Flank (SNP) | VAF 6/42 reads (14%) | catalogued as COSV57300466; called by muse, mutect2, varscan2
- SLC17A3 | c.303+228C>G | Intron (SNP) | VAF 6/23 reads (26%) | catalogued as COSV100399436; called by muse, mutect2, varscan2
- SNORD52 | chr6:31837420 C>T | 3'Flank (SNP) | VAF 21/183 reads (11%) | catalogued as COSV100794751; called by muse, mutect2, varscan2
- USH1C | c.1285-7655G>T | Intron (SNP) | VAF 5/22 reads (23%) | catalogued as COSV50018549; called by muse, mutect2, varscan2
